Gene-level copy-number profile of tumor specimen TCGA-05-4430-01A from TCGA case TCGA-05-4430, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.9 years (21,884 days).
Specimen TCGA-05-4430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.09a2d06b-a918-47fd-a1fd-ea07c0e0e185.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4430-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc8d2af3-1f26-465c-ab10-2dfc214ad0a0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,534; copy number 3: 24,544; copy number 4: 20,175; copy number 5: 3,182; copy number 6: 164; copy number 7: 3,456; copy number 8: 531; copy number 9: 98; copy number 10: 710; copy number 11: 418.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4430-01A-02D-1204-01): tumor purity 0.2, ploidy 3.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,213 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7 (broad region; genes not listed).
- chr2:111,611,639–111,884,690, 1 gene, copy number 9 (within-gene range 5–9): ANAPC1.
- chr2:111,742,586–112,764,664, 31 genes, copy number 9 (within-gene range 5–9): CENPNP2, MIR4771-2, AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1, AC093675.1, TMEM87B, AC093675.2, FBLN7, AC092645.1, ZC3H8, AC092645.2, ZC3H6, NDUFB4P6, AC115115.1, RGPD8, VINAC1P, TTL, POLR1B, Y_RNA, CHCHD5, AC012442.2, AC012442.1, AC079922.1, AC079922.2, SLC20A1, NT5DC4, CKAP2L.
- chr2:119,156,243–124,915,287, 63 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr2:131,035,092–136,078,513, 123 genes, copy number 7 (broad region; genes not listed).
- chr2:140,103,583–143,897,361, 35 genes, copy number 9: LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3, AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1, ARHGAP15, MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1, AC079793.1, AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2, AC079584.1, Y_RNA.
- chr2:199,867,396–201,229,406, 47 genes, copy number 7 (within-gene range 3–7): AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1, AC004464.1, SPATS2L, RNY4P34, AC012459.1, KCTD18, SGO2, AOX1, AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1, RNU6-31P, BICD1P1, RNA5SP115, CLK1, Y_RNA, PPIL3, RNU6-312P, NIF3L1, RNU6-762P, ORC2, AC005037.1, FAM126B, HNRNPA1P35, RPL23AP30, NDUFB3, RNU6-1206P, Metazoa_SRP, AC007272.1, RPL17P10, CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P, RPL38P5, AC007283.1, CASP10, MTND5P25.
- chr5:58,198–45,895,970, 710 genes, copy number 10 (broad region; genes not listed).
- chr5:62,146,665–63,302,056, 13 genes, copy number 7: RN7SKP157, KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3, AC114982.1, RPL35AP14, LRRC70, ISCA1P1, AC113420.1, AC025445.1.
- chr5:66,139,971–67,270,182, 13 genes, copy number 7: SREK1, AC025442.1, LINC02065, AC092353.1, AC092353.2, LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1, MAST4-AS1, CD180, AC010420.1.
- chr6:34,189,780–44,450,425, 300 genes, copy number 11 (broad region; genes not listed).
- chr6:46,652,915–46,954,943, 9 genes, copy number 11: SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1.
- chr6:49,115,537–52,087,613, 38 genes, copy number 8–11 (within-gene range 2–11): AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1, PKHD1, RN7SL580P.
- chr14:21,941,128–22,506,702, 77 genes, copy number 8 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–10,994,924, 248 genes, copy number 7 (broad region; genes not listed).
- chr20:11,536,406–18,090,715, 84 genes, copy number 8 (broad region; genes not listed).
- chr20:18,433,842–33,401,561, 310 genes, copy number 8 (broad region; genes not listed).
- chr20:40,121,041–42,063,969, 27 genes, copy number 8 (within-gene range 2–8): AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3.
- chr20:56,550,605–61,940,617, 104 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
